Somatic mutation profile of tumor specimen 0DX4FS from CCDI case PBCPIL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 2.5 years (924 days).
Specimen 0DX4FS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a5827e3-cdf5-426f-9fbd-58b68746af39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX4EQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e372bcf-b08d-4bb2-9e81-6d5acc0a00cf

The open-access MAF lists 3 somatic variants for this specimen: 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OR10C1 | c.204G>A p.S68= (on ENST00000622521; = p.S66= on NM_013941.3) | Silent (SNP) | VAF 218/749 reads (29%) | catalogued as rs758675435; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 8/158 reads (5%) | called by muse, mutect2
